Somatic mutation profile of cancer-model specimen HCM-BROD-0230-C25-85D (3D Organoid, passage 5; aliquot HCM-BROD-0230-C25-85D-01D-A83U-36), derived from the metastatic tumor of HCMI case HCM-BROD-0230-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 83.0 years (30,305 days).
Specimen HCM-BROD-0230-C25-85D: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c8a1614-07eb-4eb4-8b52-b79bd7087208.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0230-C25-10A (Blood Derived Normal), aliquot HCM-BROD-0230-C25-10A-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cdd74788-c55b-4131-83d8-946986b8e18a

The open-access MAF lists 134 somatic variants for this specimen: 102 protein-altering or splice-affecting, 30 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 93, Silent 30, Frame Shift Del 4, Nonsense Mutation 2, 5'UTR 1, Splice Site 1, 3'UTR 1, Frame Shift Ins 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A2M | c.871A>G p.S291G | Missense Mutation (SNP) | VAF 130/279 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as rs374513475; called by muse, mutect2, varscan2
- ABCB11 | c.3746T>C p.L1249S | Missense Mutation (SNP) | VAF 55/1117 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1510527; called by muse, mutect2
- APP | c.427G>A p.V143I | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs200541360; called by muse, mutect2, varscan2
- ARHGAP17 | c.403C>A p.Q135K | Missense Mutation (SNP) | VAF 218/406 reads (54%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.91); catalogued as COSV99254161; called by muse, mutect2, varscan2
- ARHGAP36 | c.1601G>A p.R534Q | Missense Mutation (SNP) | VAF 49/315 reads (16%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs376197707, COSV52265119; called by muse, mutect2, varscan2
- BRCA1 | c.2600A>C p.Q867P | Missense Mutation (SNP) | VAF 57/571 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM035956; called by muse, mutect2
- COL22A1 | c.4783C>A p.L1595I | Missense Mutation (SNP) | VAF 45/717 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs561552719, COSV100278662; called by muse, mutect2
- CTNND1 | c.892A>C p.M298L | Missense Mutation (SNP) | VAF 52/472 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62385552; called by muse, varscan2
- DSEL | c.1133G>C p.R378P | Missense Mutation (SNP) | VAF 227/588 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59494670; called by muse, mutect2, varscan2
- GRIK2 | c.950C>T p.T317M | Missense Mutation (SNP) | VAF 124/268 reads (46%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.61); catalogued as rs118175062; called by muse, mutect2, varscan2
- ISYNA1 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 128/500 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1189395680; called by muse, varscan2
- ITFG1 | c.1606A>G p.I536V | Missense Mutation (SNP) | VAF 144/264 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs763027424; called by muse, mutect2, varscan2
- JPH2 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 246/590 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1427861059, COSV60697274; called by muse, varscan2
- KDF1 | c.836T>G p.I279S | Missense Mutation (SNP) | VAF 228/232 reads (98%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs778729019; called by muse, mutect2, varscan2
- KDM5D | c.4361T>C p.V1454A | Missense Mutation (SNP) | VAF 26/438 reads (6%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs778039265; called by muse, mutect2
- MEFV | c.553G>A p.G185R | Missense Mutation (SNP) | VAF 94/705 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1266566289, COSV99561336; ClinVar: uncertain significance; called by muse, varscan2
- MIGA2 | c.1517T>C p.L506P | Missense Mutation (SNP) | VAF 44/587 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52978198; called by muse, mutect2
- OR4F15 | c.509G>C p.G170A | Missense Mutation (SNP) | VAF 34/658 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.96); catalogued as COSV99046070; called by muse, mutect2
- PCDHA13 | c.1925C>T p.A642V | Missense Mutation (SNP) | VAF 256/506 reads (51%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.036); catalogued as rs1554181316, COSV56558219; called by muse, varscan2
- PI15 | c.386C>A p.T129N | Missense Mutation (SNP) | VAF 37/327 reads (11%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.801); catalogued as rs957776786, COSV52640254; called by muse, mutect2, varscan2
- PITPNM1 | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 48/666 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1206358918; called by muse, mutect2
- POM121C | c.1100G>A p.R367Q (on ENST00000607367; = p.R125Q on NM_001099415.3) | Missense Mutation (SNP) | VAF 188/446 reads (42%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.934); catalogued as rs782598649; called by muse, varscan2
- PRKAR1B | c.873C>A p.D291E | Missense Mutation (SNP) | VAF 75/405 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs1445954537; called by muse, mutect2
- RIMBP2 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 290/656 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs756172940, COSV99900218; called by muse, mutect2
- RIN2 | c.2796C>G p.I932M (on ENST00000255006 / NM_001242581.1; = p.I883M on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/466 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); catalogued as COSV99656935; called by muse, mutect2
- RTN4R | c.1309G>A p.G437R | Missense Mutation (SNP) | VAF 62/652 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.528); catalogued as rs758157859; called by muse, mutect2
- SAMD9L | c.193G>T p.A65S | Missense Mutation (SNP) | VAF 30/612 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV100560677; called by muse, mutect2
- SFXN3 | c.823G>A p.V275M | Missense Mutation (SNP) | VAF 47/568 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs1425847604; called by muse, mutect2
- SLC38A4 | c.362A>G p.Y121C | Missense Mutation (SNP) | VAF 52/166 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201939643; called by muse, mutect2, varscan2
- SLC4A3 | c.1889G>T p.R630L | Missense Mutation (SNP) | VAF 46/584 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV56096981; called by muse, mutect2
- SPTBN2 | c.3799G>A p.A1267T | Missense Mutation (SNP) | VAF 38/577 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100017859, COSV100020835; called by muse, mutect2
- SYCP2L | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.255); catalogued as COSV51651614; called by muse, mutect2
- TNNC2 | c.440T>C p.I147T | Missense Mutation (SNP) | VAF 103/270 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs113240353; called by muse, mutect2, varscan2
- TRAF3IP2 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 156/328 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs559874598; called by muse, varscan2
- ZMYM6 | c.782C>G p.T261R | Missense Mutation (SNP) | VAF 21/374 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.47); catalogued as rs371421461; called by muse, mutect2
- ABCA13 | c.9661G>T p.E3221* | Nonsense Mutation (SNP) | VAF 24/354 reads (7%) | called by muse, mutect2
- ABCG8 | c.1978G>A p.V660M | Missense Mutation (SNP) | VAF 192/378 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.033); called by muse, varscan2
- ACOXL | c.1234T>G p.S412A (on ENST00000389811 / NM_001371254.1; = p.S382A on NM_001142807.4) | Missense Mutation (SNP) | VAF 183/374 reads (49%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ACTN4 | c.223G>T p.D75Y | Missense Mutation (SNP) | VAF 193/393 reads (49%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- AFG3L2 | c.1873A>G p.M625V | Missense Mutation (SNP) | VAF 36/366 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, varscan2
- AHNAK | c.1070G>A p.S357N | Missense Mutation (SNP) | VAF 27/585 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.466); called by muse, mutect2
- AL135905.2 | c.114C>G p.H38Q | Missense Mutation (SNP) | VAF 38/478 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.774); called by muse, mutect2
- ANKRD35 | c.2423G>C p.G808A | Missense Mutation (SNP) | VAF 43/1268 reads (3%) | SIFT tolerated (0.81); PolyPhen benign (0.006); called by muse, mutect2
- APC2 | c.1991G>C p.W664S | Missense Mutation (SNP) | VAF 49/547 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- ARPC5 | c.43G>T p.D15Y | Missense Mutation (SNP) | VAF 46/1196 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BMP2K | c.157C>G p.L53V | Missense Mutation (SNP) | VAF 130/266 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.086); called by mutect2, varscan2
- CDIPT | c.133C>A p.L45M | Missense Mutation (SNP) | VAF 111/416 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- CEACAM8 | c.638A>C p.Y213S | Missense Mutation (SNP) | VAF 41/531 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CIITA | c.7T>G p.C3G | Missense Mutation (SNP) | VAF 118/494 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CIZ1 | c.1104G>C p.E368D | Missense Mutation (SNP) | VAF 56/802 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.074); called by muse, mutect2
- DHX36 | c.2047C>A p.Q683K | Missense Mutation (SNP) | VAF 58/606 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.017); called by muse, mutect2
- DNAH7 | c.157del p.H53Tfs*11 | Frame Shift Del (DEL) | VAF 275/623 reads (44%) | called by mutect2, pindel, varscan2
- DOHH | c.469G>T p.D157Y | Missense Mutation (SNP) | VAF 26/686 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2
- DSG2 | c.57C>A p.N19K | Missense Mutation (SNP) | VAF 109/223 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.066); called by mutect2, varscan2
- DYTN | c.1411_1421del p.K471Efs*4 | Frame Shift Del (DEL) | VAF 235/499 reads (47%) | called by mutect2, pindel, varscan2
- EPHA5 | c.2785G>T p.V929F | Missense Mutation (SNP) | VAF 34/613 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- ERVW-1 | c.1007G>C p.G336A | Missense Mutation (SNP) | VAF 45/600 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.724); called by muse, mutect2
- FAM43B | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, varscan2
- GPAM | c.700A>C p.I234L | Missense Mutation (SNP) | VAF 163/361 reads (45%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- GPT | c.5C>A p.A2D | Missense Mutation (SNP) | VAF 114/292 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2
- GRIK1 | c.2385_2391del p.A796Ffs*11 | Frame Shift Del (DEL) | VAF 17/194 reads (9%) | called by mutect2, pindel
- GZF1 | c.65A>T p.H22L | Missense Mutation (SNP) | VAF 220/449 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- IL17F | c.33+1G>T p.X11_splice | Splice Site (SNP) | VAF 210/444 reads (47%) | called by muse, mutect2, varscan2
- ILRUN | c.221C>G p.S74C | Missense Mutation (SNP) | VAF 211/459 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- JAKMIP3 | c.869A>C p.K290T | Missense Mutation (SNP) | VAF 60/401 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- KCNC2 | c.1069A>G p.R357G | Missense Mutation (SNP) | VAF 61/298 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- L3MBTL2 | c.26A>T p.E9V | Missense Mutation (SNP) | VAF 100/218 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.145); called by muse, mutect2
- LTBP3 | c.2208C>G p.S736R | Missense Mutation (SNP) | VAF 28/495 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.005); called by muse, mutect2
- LY9 | c.95T>G p.L32R | Missense Mutation (SNP) | VAF 162/846 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAGEE2 | c.784A>G p.T262A | Missense Mutation (SNP) | VAF 38/294 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, varscan2
- MAST4 | c.962C>A p.T321K (on ENST00000403625 / NM_001164664.2; = p.T132K on NM_015183.3) | Missense Mutation (SNP) | VAF 16/442 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYO7B | c.4094C>G p.P1365R | Missense Mutation (SNP) | VAF 98/480 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.07); called by muse, varscan2
- NLRP10 | c.1099C>T p.Q367* | Nonsense Mutation (SNP) | VAF 242/514 reads (47%) | called by muse, varscan2
- OGFOD3 | c.742T>C p.S248P | Missense Mutation (SNP) | VAF 73/622 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR14K1 | c.69G>T p.R23S | Missense Mutation (SNP) | VAF 98/1312 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.018); called by muse, mutect2
- PCDH11X | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 24/260 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.102); called by muse, varscan2
- PGAM4 | c.484del p.R162Efs*10 | Frame Shift Del (DEL) | VAF 291/413 reads (70%) | called by mutect2, pindel, varscan2
- PITPNM1 | c.841G>T p.A281S | Missense Mutation (SNP) | VAF 47/663 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2
- PKP3 | c.1265dup p.N422Kfs*266 | Frame Shift Ins (INS) | VAF 76/222 reads (34%) | called by mutect2, pindel, varscan2
- RECQL4 | c.1421A>T p.E474V | Missense Mutation (SNP) | VAF 96/414 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.543); called by muse, varscan2
- RGPD2 | c.3980T>G p.F1327C | Missense Mutation (SNP) | VAF 148/447 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- RNF40 | c.1586C>T p.T529I | Missense Mutation (SNP) | VAF 48/534 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2
- RTCB | c.594G>T p.R198S | Missense Mutation (SNP) | VAF 49/500 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- SH3GL3 | c.435A>T p.L145F | Missense Mutation (SNP) | VAF 19/291 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.415); called by muse, mutect2
- SLA | c.827A>G p.D276G (on ENST00000338087 / NM_001045556.3; = p.D316G on NM_006748.4) | Missense Mutation (SNP) | VAF 146/291 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- SLC17A7 | c.1450A>G p.I484V | Missense Mutation (SNP) | VAF 44/536 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.011); called by muse, mutect2
- SMARCC1 | c.2572G>C p.E858Q | Missense Mutation (SNP) | VAF 33/220 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- SMTN | c.2426G>T p.C809F | Missense Mutation (SNP) | VAF 19/553 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SNX6 | c.94A>G p.K32E (on ENST00000652385; = p.K20E on NM_152233.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/156 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.087); called by muse, mutect2
- TEC | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 194/395 reads (49%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- THEGL | c.1315G>A p.D439N | Missense Mutation (SNP) | VAF 165/384 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- TIE1 | c.3172A>C p.T1058P | Missense Mutation (SNP) | VAF 55/448 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMC3 | c.1681G>A p.V561M | Missense Mutation (SNP) | VAF 30/478 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- TMEM9 | c.74A>T p.E25V | Missense Mutation (SNP) | VAF 36/1085 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); called by muse, mutect2
- TP53BP2 | c.1442T>C p.L481P (on ENST00000343537 / NM_001031685.3; = p.L352P on NM_005426.2) | Missense Mutation (SNP) | VAF 175/1037 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- TPRG1L | c.224T>C p.V75A | Missense Mutation (SNP) | VAF 185/188 reads (98%) | SIFT tolerated (0.1); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- TRAPPC12 | c.1495G>C p.D499H | Missense Mutation (SNP) | VAF 34/583 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); called by muse, mutect2
- VIP | c.66G>T p.Q22H | Missense Mutation (SNP) | VAF 202/207 reads (98%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, varscan2
- VN1R2 | c.153G>C p.L51F | Missense Mutation (SNP) | VAF 54/667 reads (8%) | PolyPhen possibly damaging (0.587); called by muse, mutect2
- ZNF214 | c.1821_*3del | Nonstop Mutation (DEL) | VAF 65/118 reads (55%) | called by mutect2, pindel, varscan2
- ZNF611 | c.809A>G p.H270R | Missense Mutation (SNP) | VAF 140/370 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2
- ZNF813 | c.545G>A p.C182Y | Missense Mutation (SNP) | VAF 30/287 reads (10%) | SIFT tolerated (1); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- C19orf85 | c.42C>T p.P14= | Silent (SNP) | VAF 290/614 reads (47%) | catalogued as rs1179736243; called by muse, mutect2, varscan2
- CCDC186 | c.411A>G p.S137= | Silent (SNP) | VAF 134/247 reads (54%) | called by muse, varscan2
- CHST2 | c.531G>A p.S177= | Silent (SNP) | VAF 66/986 reads (7%) | catalogued as rs368136453; called by muse, mutect2
- ENPP3 | c.2043C>T p.F681= | Silent (SNP) | VAF 210/420 reads (50%) | catalogued as rs376129649, COSV62953269; called by muse, mutect2, varscan2
- FMN2 | c.1626G>C p.L542= | Silent (SNP) | VAF 149/975 reads (15%) | called by muse, mutect2, varscan2
- GATA6 | c.279A>G p.G93= | Silent (SNP) | VAF 235/535 reads (44%) | called by muse, mutect2, varscan2
- GPER1 | c.177G>T p.L59= | Silent (SNP) | VAF 66/647 reads (10%) | called by muse, mutect2
- HIP1 | c.90G>C p.A30= | Silent (SNP) | VAF 36/674 reads (5%) | catalogued as rs782468864; called by muse, mutect2
- KCND3 | c.1308C>G p.G436= | Silent (SNP) | VAF 22/350 reads (6%) | catalogued as rs190703406; ClinVar: benign / likely benign; called by muse, mutect2
- KLHL6 | c.225C>A p.I75= | Silent (SNP) | VAF 196/642 reads (31%) | catalogued as COSV58068705; called by muse, varscan2
- MFSD14A | c.1107C>A p.V369= | Silent (SNP) | VAF 112/114 reads (98%) | catalogued as COSV54928681; called by muse, varscan2
- MRTFB | c.621G>T p.G207= | Silent (SNP) | VAF 56/706 reads (8%) | called by muse, mutect2
- MUC19 | c.246C>T p.T82= | Silent (SNP) | VAF 12/268 reads (4%) | called by muse, mutect2
- MYD88 | c.132G>C p.A44= | Silent (SNP) | VAF 494/504 reads (98%) | catalogued as COSV57172957; called by muse, varscan2
- NEO1 | c.354A>G p.K118= | Silent (SNP) | VAF 48/778 reads (6%) | catalogued as rs143861097; called by muse, mutect2
- NOX5 | c.903G>A p.L301= | Silent (SNP) | VAF 48/944 reads (5%) | called by muse, mutect2
- NRDE2 | c.2460C>G p.L820= | Silent (SNP) | VAF 298/305 reads (98%) | catalogued as COSV62965057; called by muse, mutect2, varscan2
- OAT | c.1186C>A p.R396= | Silent (SNP) | VAF 36/414 reads (9%) | catalogued as CM890087; called by muse, mutect2
- PADI3 | c.1902C>T p.F634= | Silent (SNP) | VAF 40/218 reads (18%) | called by muse, varscan2
- POLR1B | c.327C>A p.T109= | Silent (SNP) | VAF 61/275 reads (22%) | called by muse, mutect2, varscan2
- RPL6 | c.273T>G p.T91= | Silent (SNP) | VAF 165/409 reads (40%) | called by muse, mutect2, varscan2
- SLC35C2 | c.360T>G p.A120= | Silent (SNP) | VAF 34/464 reads (7%) | called by muse, mutect2
- SPNS3 | c.1102C>T p.L368= | Silent (SNP) | VAF 38/367 reads (10%) | called by muse, varscan2
- TAS2R38 | c.954C>T p.S318= | Silent (SNP) | VAF 182/367 reads (50%) | catalogued as rs1554444320; called by mutect2, varscan2
- TENT4A | c.444C>T p.A148= | Silent (SNP) | VAF 116/299 reads (39%) | called by muse, mutect2, varscan2
- TEX15 | c.2181C>T p.N727= (on ENST00000256246; = p.N1110= on NM_001350162.2) | Silent (SNP) | VAF 217/410 reads (53%) | catalogued as rs372490853; called by muse, varscan2
- TLR5 | c.2115A>G p.T705= | Silent (SNP) | VAF 396/1184 reads (33%) | catalogued as rs775966863; called by muse, varscan2
- TRAM1 | c.333C>T p.F111= | Silent (SNP) | VAF 33/382 reads (9%) | catalogued as COSV51600663; called by muse, mutect2
- TSSK3 | c.216G>A p.Q72= | Silent (SNP) | VAF 182/449 reads (41%) | catalogued as COSV61983038, COSV61983228; called by muse, mutect2, varscan2
- ZNF568 | c.558C>T p.I186= | Silent (SNP) | VAF 108/275 reads (39%) | called by muse, mutect2, varscan2
- BRD2 | c.-1080G>A | 5'UTR (SNP) | VAF 56/476 reads (12%) | catalogued as rs965308357; called by muse, mutect2, varscan2
- VKORC1L1 | c.*23C>G | 3'UTR (SNP) | VAF 46/358 reads (13%) | called by muse, varscan2
